Gene-level copy-number profile of tumor specimen TCGA-23-2079-01A from TCGA case TCGA-23-2079, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 46.9 years (17,122 days).
Specimen TCGA-23-2079-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.41902ab1-665f-40dd-88f6-89d3efdbf897.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-23-2079-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fe6088fe-3ace-4149-8269-ae061fd74721

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,292; copy number 2: 31,751; copy number 3: 14,257; copy number 4: 2,541; copy number 5: 1,605; copy number 6: 1,473; copy number 7: 671; copy number 8: 32; copy number 10: 194.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-23-2079-01A-01D-0663-01): tumor purity 0.79, ploidy 2.51, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,975 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:32,292,083–62,451,804, 771 genes, copy number 6 (broad region; genes not listed).
- chr3:123,282,296–123,449,090, 1 gene, copy number 5 (within-gene range 3–5): ADCY5.
- chr3:123,490,820–125,375,325, 30 genes, copy number 5 (within-gene range 4–5): HACD2, MYLK-AS1, MYLK, MYLK-AS2, AC020634.2, AC020634.1, CCDC14, ROPN1, KALRN, MIR5002, RPL7P15, MIR6083, RNU6-143P, AC022336.2, UMPS, MIR544B, AC022336.1, ITGB5, ITGB5-AS1, AC022336.3, 7SK, ENO1P3, MUC13, HEG1, RNA5SP137, AC117488.1, SLC12A8, RNU6-230P, MIR5092, ZNF148.
- chr3:141,228,726–198,222,513, 997 genes, copy number 5–10 (broad region; genes not listed).
- chr5:58,198–19,234,487, 353 genes, copy number 5 (broad region; genes not listed).
- chr6:167,607–41,163,186, 1,183 genes, copy number 5–7 (broad region; genes not listed).
- chr6:43,171,269–58,438,364, 268 genes, copy number 6 (broad region; genes not listed).
- chr7:145,039,999–148,420,998, 12 genes, copy number 5 (within-gene range 4–5): RPL7P59, AC004911.1, DPY19L4P2, AC006007.1, AC073308.1, CNTNAP2, AC073418.1, Y_RNA, CNTNAP2-AS1, DUTP3, RANP2, MIR548F4.
- chr8:102,417,979–107,506,416, 80 genes, copy number 5 (broad region; genes not listed).
- chr8:135,859,369–145,066,685, 225 genes, copy number 5–6 (broad region; genes not listed).
- chr10:73,785,606–76,560,168, 55 genes, copy number 5 (within-gene range 4–5): ZSWIM8, AC022400.8, ZSWIM8-AS1, AC022400.5, NDST2, CAMK2G, AC022400.1, AC022400.2, PLAU, C10orf55, VCL, AL596247.1, AP3M1, ADK, TIMM9P1, RPSAP6, RAB5CP1, AC022540.1, MRPL35P3, Y_RNA, NDUFA8P1, POLR3DP1, FAM32CP, AC063962.1, KAT6B, AC018511.2, AC018511.1, DUSP29, AC018511.6, PPIAP13, DUSP13, SAMD8, RPS26P42, VDAC2, COMTD1, ZNF503-AS1, RPL39P25, HMGA1P5, AC010997.3, AC010997.1, SPA17P1, ZNF503, ZNF503-AS2, AC010997.5, AC010997.4, AC010997.2, LRMDA, AC010997.6, MIR606, AL589863.2, AL589863.1, AL731568.1, RN7SL518P, RNU6-673P, AC012048.1.

Autosomal genes at a single copy (total copy number 1): 6,347. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
